Gene-level copy-number profile of tumor specimen TCGA-D8-A27R-01A from TCGA case TCGA-D8-A27R, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 41.4 years (15,122 days).
Specimen TCGA-D8-A27R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.da7c504e-b884-40e3-8c4b-6c7936a68a5c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D8-A27R-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4a69ae94-86a2-4243-b3a1-b41d17ff015b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 94; copy number 2: 14,354; copy number 3: 15,479; copy number 4: 21,804; copy number 5: 3,189; copy number 6: 1,152; copy number 7: 1,440; copy number 8: 699; copy number 9: 802; copy number 10: 639; copy number 11: 2; copy number 12: 8; copy number 13: 141; copy number 14: 14; copy number 21: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D8-A27R-01A-11D-A16C-01): tumor purity 0.4, ploidy 3.51, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,570 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:223,051,814–223,838,027, 8 genes, copy number 12 (within-gene range 7–12): KCNE4, RN7SL807P, HIGD1AP4, AC013448.1, AC013448.2, SCG2, MLXP1, AP1S3.
- chr5:60,021,249–60,548,813, 7 genes, copy number 13 (within-gene range 2–13): AC034234.1, RNU6-806P, AC109486.1, SETP21, AC109486.2, PART1, AC109486.3.
- chr5:96,814,028–97,690,180, 17 genes, copy number 10–21 (within-gene range 3–21): AC009126.1, ERAP2, LNPEP, AC008850.1, Y_RNA, SETP22, LIX1-AS1, LIX1, RIOK2, RNU1-73P, AC008883.3, AC008883.1, AC008883.2, AC074133.1, YTHDF1P1, AC106748.1, LINC01340.
- chr8:33,338,867–38,409,527, 95 genes, copy number 13 (broad region; genes not listed).
- chr8:38,408,048–38,408,742, 1 gene, copy number 13: AC087623.3.
- chr8:38,728,186–39,522,852, 14 genes, copy number 14 (within-gene range 5–14): TACC1, AC067817.1, AC067817.2, PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10, AC105185.1, ADAM5, ADAM3A.
- chr8:40,104,169–40,520,158, 7 genes, copy number 13: AC087518.1, LINC02866, TCIM, AC022733.1, SIRLNT, AC105999.1, AC010857.1.
- chr8:46,028,804–51,321,118, 78 genes, copy number 9 (broad region; genes not listed).
- chr8:63,586,000–63,693,249, 3 genes, copy number 13: AC018953.1, RN7SKP135, AC018953.2.
- chr8:69,110,513–145,066,685, 1,193 genes, copy number 9–13 (broad region; genes not listed).
- chr9:35,814,451–35,865,518, 1 gene, copy number 10 (within-gene range 6–10): TMEM8B.
- chr9:35,859,055–37,090,928, 35 genes, copy number 10: OR13E1P, OR13J1, NDUFA5P4, HRCT1, SPAAR, AL135841.1, PGAM1P2, OR2S2, OR2S1P, YBX1P10, OR13C6P, OR13C7, OR2AM1P, RECK, AL138834.1, GLIPR2, CCIN, CLTA, GNE, RNU4-53P, HMGB3P24, RNF38, MELK, AL442063.1, AL450267.2, MIR4475, PAX5, AL450267.1, MIR4540, MIR4476, AL161781.2, AL161781.1, LINC01400, AL512604.3, EBLN3P.
- chr9:73,474,378–73,548,331, 2 genes, copy number 11 (within-gene range 2–11): DPP3P2, AL451127.2.
- chr9:111,896,814–114,398,503, 63 genes, copy number 10 (broad region; genes not listed).
- chr14:52,707,178–53,991,995, 25 genes, copy number 13: PSMC6, STYX, GNPNAT1, AL139317.3, AL139317.5, AL139317.1, AL139317.2, FERMT2, AL139317.4, AL352979.4, AL352979.1, AL352979.3, DDHD1, AL352979.2, AL356020.1, AL365295.1, AL365295.2, AL163953.1, RPS3AP46, LINC02331, AL138479.1, MIR5580, BMP4, AL138479.2, ATP5F1CP1.
- chr20:61,252,261–62,367,312, 21 genes, copy number 9 (within-gene range 5–9): CDH4, AL365229.1, BX640515.1, AL160412.1, AL162457.1, AL162457.2, TAF4, MIR1257, AL137077.1, MIR3195, AL137077.2, LSM14B, PSMA7, SS18L1, MTG2, HRH3, OSBPL2, ADRM1, AL354836.1, LAMA5, MIR4758.

Autosomal genes at a single copy (total copy number 1): 94. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
